Surgical pathology report (de-identified scan), TCGA case TCGA-93-7347, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - St. Louis, specimen TCGA-93-7347-01A (Primary Tumor).

[page 1 of 4]
**SURGICAL PATHOLOGY REPORT
FINAL**

Patient Name:

DOB:

Gender:

LFB:

Physician:

Service: Cardiothoracic Surgery

Location:

MRN:

Hospital #:

Patient Type:

Accession

ID:

Accession

ID:

Accession

ID:

DIAGNOSIS:

LUNG, RIGHT UPPER LOBE, WEDGE EXCISION (INCLUDING FS1)
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH BRONCHIOLOALVEOLAR
CARCINOMA FEATURES, 1.5 CM
- NO DEFINITIVE LYMPHOVASCULAR INVASION IDENTIFIED
- PLEURAL FREE OF TUMOR
- CARCINOMA PRESENT AT INKED STAPLE MARGIN
- FREE SYNOPSIS

LYMPH NODE, LEVEL 10, EXCISION (FS2)
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LYMPH NODE, LEVEL 10 #2, EXCISION (FS3)
- RARE MUCINOUS CELLS NON-DIAGNOSTIC FOR CARCINOMA IN ONE LYMPH NODE (SEE
COMMENT)

LYMPH NODE, LEVEL 11, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LUNG, RIGHT UPPER LOBE, LOBECTOMY (INCLUDING FS4)
- MULTIFOCAL ATYPICAL ADENOMATOUS HYPERPLASIA
BRONCHIAL MARGIN FREE OF TUMOR

LYMPH NODES, PERIBRONCHIAL, LOBECTOMY
- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2)
- HYALINIZED AND CALCIFIED GRANULOMA

LYMPH NODE, 4R, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LYMPH NODE, 2R, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LYMPH NODE, 10R, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

LYMPH NODE, SUBCARINAL, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

Intraoperative Consultation:

Brought to frozen section 'right upper lobe wedge lung,' consisting of a 8.5 x 3.8 x 2.4 cm segment of lung with a 9.5 cm staple margin. Sectioned to show a 1.5 x 1.5 x 1.1 cm tan-white firm mass grossly at the stapled margin. Representative section frozen as 'FS1.' Tissue taken for [REDACTED] Rest for permanent." by [REDACTED] M.D.

Brought to frozen 'right upper lobe with bronchial margins,' consisting of two portions of lung measuring 13.7 x 8.4 x 3.3 cm and 7.5 x 3.7 x 1.4 cm. Bronchial margin of the largest portion taken as 'FS4.' Rest for permanent." by [REDACTED] M.D.

FS1: Lung, right upper lobe, wedge excision
- Adenocarcinoma," by [REDACTED]

FS2: Level 10 lymph node, biopsy
- No evidence of malignancy," by [REDACTED]

FS3: #2 level 10 lymph node, biopsy
- Rare mucinous cells that are absent on deeper level, nondiagnostic for carcinoma," by [REDACTED] Ph.D. / [REDACTED] M.D. / [REDACTED] M.D.

FS4: Right upper lobe, bronchial margins, lobectomy
- No evidence of malignancy," by [REDACTED]

Microscopic Description and Comment:

The level 10 #2 lymph node that was frozen as FS3 shows rare mucinous cells on the initial frozen section slide only. These are not seen on the permanent sections. The cells are not considered diagnostic of malignancy since they are histologically bland and are morphologically different from the adenocarcinoma in the patient's lung.

History:

The patient is a [REDACTED]
with lymph node dissection.

with a right upper lobe lung mass. Operative procedure: Right upper lobectomy

Specimen(s) Received:

- A: LUNG, RIGHT UPPER LOBE WEDGE
- B: LYMPH NODE, LEVEL 10
- C: LYMPH NODE, LEVEL 10 #2
- D: LYMPH NODE, LEVEL 11
- E: LUNG, RIGHT UPPER WITH BRONCHIAL MARGINS
- F: LYMPH NODE, 4R

[page 3 of 4]
1 LYMPH NODE, 2R
1 LYMPH NODE, SUSPICIOUS 10R
1 LYMPH NODE, SUBCARINAL

SURGICAL PATHOLOGY REPORT

Gross Description:

The specimens are received in nine formalin-filled containers each labeled. The first container is labeled "right upper lobe wedge lung" and "FS1/X." It contains a tissue cassette that holds a 1.2 x 1.0 x 0.3 cm portion of friable yellow tissue. Labeled A1 (FS1). Also in the container is a lung wedge measuring 8.5 x 3.8 x 2.4 cm. The pleural surface is purple-pink and smooth. There is a 10.5 cm staple line. The lung has been previously sectioned to show a well-demarcated 1.5 x 1.0 x 1.0 cm yellow nodule that abuts the stapled margin. The mass is 1 mm from the nearest pleural surface and the pleural surface is disrupted but it does not appear that the mass caused any pleural thickening. The remaining lung parenchyma is spongy and pink and shows no other lesions. Labeled A2 - mass relative to staple line; A3 - mass relative to pleura; A4 - mass relative to pleura; A5 - unremarkable lung. Jar 1.

The second container is labeled "level 10 lymph node" and "FS2." It contains two pieces of black lymphoid tissue; the larger measures 0.4 x 0.4 x 0.2 cm, the smaller measures 0.4 x 0.3 x 0.2 cm. Labeled B1 (FS2). Jar 0.

The third container is labeled "level 10 lymph node" and "FS3." It contains multiple pieces of black lymphoid tissue that aggregate to 1.5 x 1.2 x 0.4 cm. Labeled C1 (FS3). Jar 0.

The fourth container is labeled "level 11 lymph node." It contains multiple pieces of lymphoid tissue that aggregate to 2.2 x 2.0 x 0.4 cm. Labeled D1. Jar 0.

The fifth container is labeled "right upper lobe with bronchial margins." It contains a tissue cassette labeled "FS4" that contains a bronchial resection margin measuring 2.1 x 1.0 x 0.3 cm. Labeled E1 (FS4). Also in the container are two pieces of lung; the smaller is a triangular-shaped piece that measures 7.1 x 4.0 x 1.5 cm and has a 12.5 cm staple line. The pleural surface is dark purple and smooth. The second piece is a right upper lobe specimen with a tan-purple pleural surface that is smooth. There are two staple lines, one measuring 7.5 cm and the other that crosses the bronchial margin measuring 9.5 cm. The lung is sectioned to show pink, spongy parenchyma with no masses or lesions. The staple line from the previous wedge resection is removed and the underlying lung parenchyma is inked black. The smaller wedge is sectioned to show a spongy, red parenchyma and no focal lesions. Labeled E2 - shave of staple line and hilum; E3 - section from opposite staple line; E4 - vascular margins; E5 - hilar lymph node; E6 - unremarkable lung from larger piece; E7 - representative section from smaller piece. Jar 1.

The sixth container is labeled "4R lymph node." It contains two fragmented pieces of lymphoid tissue; the smaller measures 2.5 x 1.0 x 0.7 cm, the larger measures 2.4 x 1.7 x 1.0 cm. The larger fragment is bisected. Labeled F1 and F2. Jar 0.

The seventh container is labeled "2R lymph node." It contains two pieces of lymphoid tissue that are both disrupted. Both measure roughly 1.7 x 1.0 x 0.7 cm. Labeled G1. Jar 0.

The eighth container is labeled "suspicious 10R lymph node." It contains multiple black fragments of lymphoid tissue that aggregate to 1.1 x 0.7 x 0.3 cm. Wrapped. Labeled H1. Jar 0.

The ninth container is labeled "subcarinal lymph node." It contains multiple black fragments of lymph node that aggregate to 3.5 x 3.5 x 1.0 cm. Sectioned. Labeled I1 to I3. Jar 0.

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is adenocarcinoma, acinar (usual) type

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

HISTOLOGIC GRADE (G)

The grade of the tumor is moderately differentiated (G2)

TUMOR SIZE

The maximum dimension of the tumor is 1.5 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is absent (L0)

VENOUS INVASION

Venous invasion by tumor is absent (V0)

ARTERIAL INVASION

Arterial invasion by tumor is absent

PLEURAL INVOLVEMENT

Pleural involvement is absent

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

PRIMARY TUMOR (T)

Tumor $\leq$ 2 cm in greatest dimension (T1a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically; no examination for ITC (pN0)

The total number of lymph nodes examined is 9

The total number of metastatically-involved lymph nodes is 0

Extranodal extension by tumor is not applicable; no nodal metastases are present

See comment

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

STAGE GROUPING

The overall international stage is T1aN0MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 601642a8-42b9-4fbf-b5c9-0e6278b0eac5 (TCGA-93-7347.A89EF8AB-8AF7-4906-844E-EB216316F584.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).